CCDI case PBBRAT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/c454fde9-75d2-47c6-a0da-26af87c23ed6

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 24.4 years (8,906 days).

Biospecimens (3 samples)
- Sample 0DESU1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DESU2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DESU3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
